Somatic mutation profile of tumor specimen TCGA-B0-5402-01A (aliquot TCGA-B0-5402-01A-01D-1501-10) from TCGA case TCGA-B0-5402, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 64.3 years (23,477 days).
Specimen TCGA-B0-5402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ad4a254-6103-4ca5-b204-c8fa6ad61474.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5402-11A (Solid Tissue Normal), aliquot TCGA-B0-5402-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550978b1-408b-42bf-b818-48c1e17ee2e6

The open-access MAF lists 51 somatic variants for this specimen: 47 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 2, Silent 2, Intron 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM29 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs544557652, COSV63662285; called by muse, mutect2, varscan2
- ARHGAP28 | c.714G>T p.R238S (on ENST00000383472 / NM_001366230.1; = p.R79S on NM_001010000.3) | Missense Mutation (SNP) | VAF 129/437 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV51640428; called by muse, mutect2, varscan2
- ATP1B4 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 37/57 reads (65%) | catalogued as COSV54313343; called by muse, mutect2, varscan2
- C11orf45 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV57967418; called by muse, mutect2, varscan2
- CCDC81 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 121/366 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53579485; called by muse, varscan2
- CDX1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs371789864, COSV51568406; called by muse, varscan2
- CEP164 | c.3979G>A p.A1327T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV54042698; called by muse, varscan2
- CHMP2B | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 166/373 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV55462516; called by muse, mutect2, varscan2
- COL15A1 | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66646403; called by muse, mutect2, varscan2
- COL6A3 | c.4786G>A p.V1596M | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55094802; called by muse, mutect2, varscan2
- DPYSL3 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58327902; called by muse, mutect2, varscan2
- FASTKD3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.286); catalogued as rs1296715570, COSV52944811; called by muse, mutect2, varscan2
- FBN2 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 151/284 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1233430118, COSV52522869; called by muse, mutect2, varscan2
- GALNTL5 | c.557A>C p.D186A | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV67180423; called by muse, mutect2, varscan2
- GALT | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.518); catalogued as CM151308, COSV66593133; called by muse, mutect2, varscan2
- GOLGA3 | c.3304C>T p.R1102C | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs866467183, COSV52634945; called by muse, mutect2, varscan2
- IFT88 | c.1335G>T p.E445D (on ENST00000319980 / NM_001318493.2; = p.E436D on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/562 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV60674559; called by muse, mutect2, varscan2
- IP6K1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs746238797, COSV58663814; called by muse, mutect2, varscan2
- KLK11 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs753143187, COSV51575660, COSV99142061; called by muse, varscan2
- LRCH1 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60849022; called by muse, mutect2, varscan2
- LRIF1 | c.2239_2241del p.R747del | In Frame Del (DEL) | VAF 44/264 reads (17%) | catalogued as rs1338237044; called by pindel, varscan2
- LY75-CD302 | c.5314C>A p.L1772M | Missense Mutation (SNP) | VAF 26/485 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.269); catalogued as COSV52033695, COSV52033788; called by muse, mutect2
- MAK16 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 172/555 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV62452933; called by muse, varscan2
- MAP4K4 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs1439407435, COSV56333795; called by muse, mutect2, varscan2
- OR10G7 | c.488T>A p.F163Y | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57867609; called by muse, mutect2, varscan2
- OR5M8 | c.796T>G p.S266A | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1275952570, COSV59117249; called by muse, mutect2, varscan2
- PCDHB6 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV50695820, COSV50696131, COSV50703367; called by muse, mutect2, varscan2
- PDE1B | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54490346; called by muse, mutect2, varscan2
- PDE3A | c.2214T>A p.Y738* | Nonsense Mutation (SNP) | VAF 231/770 reads (30%) | catalogued as COSV62975642; called by muse, mutect2, varscan2
- PDZD2 | c.4853C>A p.P1618H | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56862208; called by muse, mutect2, varscan2
- PTK7 | c.1503G>C p.K501N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV57849449; called by muse, mutect2, varscan2
- RARRES1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 180/630 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.716); catalogued as COSV52962833; called by muse, mutect2, varscan2
- RPL3L | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51907163; called by muse, mutect2, varscan2
- SETD2 | c.1783_1784del p.S595Kfs*3 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as COSV57441433; called by mutect2, pindel, varscan2
- SF3A3 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV65956081; called by muse, mutect2
- SLC9B2 | c.8A>G p.D3G | Missense Mutation (SNP) | VAF 206/679 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV60020052; called by muse, mutect2, varscan2
- STEAP1 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 157/1138 reads (14%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.997); catalogued as COSV51882076; called by muse, mutect2, varscan2
- TBX22 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64786654; called by muse, mutect2
- TGM6 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.749); catalogued as COSV52481418; called by muse, mutect2, varscan2
- TIMELESS | c.2296C>G p.L766V | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57512570; called by muse, mutect2, varscan2
- TLDC2 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV54114722; called by muse, mutect2, varscan2
- USP5 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV57538305, COSV57538598; called by muse, mutect2, varscan2
- VHL | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as CD983007, COSV56546200, COSV56564223, COSV56566424, COSV56567674; called by muse, mutect2, varscan2
- ZNF467 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV57373736; called by muse, mutect2, varscan2
- ZRANB3 | c.2515G>C p.V839L | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV51505762; called by muse, mutect2, varscan2
- GSDME | c.671del p.L224Yfs*3 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- JAK1 | c.1167_1169del p.N389del | In Frame Del (DEL) | VAF 89/320 reads (28%) | called by pindel, varscan2
- COL22A1 | c.831G>A p.V277= | Silent (SNP) | VAF 58/202 reads (29%) | catalogued as COSV57343483; called by muse, mutect2, varscan2
- HCN1 | c.2106G>A p.A702= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs1344539030, COSV57494147; called by muse, mutect2, varscan2
- ETFB | c.58-170C>G | Intron (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100495768; called by muse, mutect2
- NDUFV3 | c.170-5033A>G | Intron (SNP) | VAF 50/130 reads (38%) | catalogued as COSV61088017; called by muse, mutect2, varscan2
